Somatic mutation profile of tumor specimen TCGA-FV-A3R3-01A (aliquot TCGA-FV-A3R3-01A-11D-A22F-10) from TCGA case TCGA-FV-A3R3, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 39.0 years (14,231 days).
Specimen TCGA-FV-A3R3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c006fd85-576c-4aad-aafb-3444a43d5335.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FV-A3R3-10A (Blood Derived Normal), aliquot TCGA-FV-A3R3-10A-01D-A22F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b93a072-fffa-43d9-bb89-80fbce4421ff

The open-access MAF lists 57 somatic variants for this specimen: 43 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 10, Nonsense Mutation 3, Intron 2, Frame Shift Del 2, 3'UTR 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 27/92 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP13 | c.6437T>G p.V2146G (on ENST00000394518 / NM_007200.5; = p.V2150G on NM_006738.6) | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63459145; called by muse, mutect2, varscan2
- AMMECR1 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.759); catalogued as COSV53317981; called by muse, mutect2, varscan2
- ARHGAP24 | c.245A>T p.K82M | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV67841234, COSV67841452; called by muse, mutect2, varscan2
- BAZ1A | c.4085A>G p.K1362R | Missense Mutation (SNP) | VAF 35/317 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV62410446; called by muse, mutect2, varscan2
- BMP5 | c.1237C>G p.H413D | Missense Mutation (SNP) | VAF 20/263 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.216); catalogued as COSV63702682, COSV63703534; called by muse, mutect2
- C9orf57 | c.461G>T p.C154F (on ENST00000377024 / NM_001371610.1; = p.C132F on NM_001128618.2) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65462793; called by muse, mutect2, varscan2
- CHL1 | c.2176A>G p.K726E (on ENST00000397491 / NM_001253387.1; = p.K742E on NM_006614.4) | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV56594747; called by muse, mutect2, varscan2
- COQ6 | c.402T>G p.D134E | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV53178896; called by muse, mutect2, varscan2
- COX18 | c.862G>T p.V288L | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV55720615; called by muse, mutect2, varscan2
- CRY1 | c.130T>C p.S44P | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV50483462; called by muse, mutect2
- DAZAP1 | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs773570832, COSV51832895; called by muse, mutect2
- DENND4A | c.4464A>T p.L1488F | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71265940; called by muse, mutect2
- DIDO1 | c.5596G>A p.A1866T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs746504551, COSV56624007; called by muse, mutect2, varscan2
- ELOVL3 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs150611171; called by muse, mutect2, varscan2
- FAM184B | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as rs977021514, COSV99401932; called by muse, mutect2
- FSD2 | c.922A>G p.T308A | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as COSV58010425; called by muse, mutect2, varscan2
- GLI2 | c.3536G>A p.G1179E (on ENST00000361492 / NM_001374353.1; = p.G1196E on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.211); catalogued as COSV58042905; called by muse, mutect2, varscan2
- GRIA2 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as rs777296512, COSV52391073; called by muse, mutect2, varscan2
- KRT83 | c.574C>A p.L192M | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.511); catalogued as COSV53340530; called by muse, mutect2
- LIFR | c.2725G>T p.E909* | Nonsense Mutation (SNP) | VAF 14/86 reads (16%) | catalogued as COSV54691180; called by mutect2, varscan2
- MID2 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 11/71 reads (15%) | catalogued as COSV53309673; called by muse, mutect2, varscan2
- MUC16 | c.27265A>C p.T9089P | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.076); catalogued as COSV67469598; called by muse, mutect2, varscan2
- NEK2 | c.21C>A p.D7E | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV65356107; called by muse, mutect2, varscan2
- NEU1 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV57667393; called by muse, mutect2
- NPC1 | c.651G>A p.M217I | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1255173529, COSV52579336, COSV99341418; called by muse, mutect2
- PCDHGA4 | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.009); catalogued as rs1561513386, COSV53958783; called by muse, mutect2, varscan2
- PDE4D | c.565G>T p.E189* (on ENST00000340635 / NM_001104631.2; = p.E53* on NM_006203.4) | Nonsense Mutation (SNP) | VAF 24/73 reads (33%) | catalogued as COSV58957999; called by muse, mutect2, varscan2
- POLR2A | c.989A>T p.Q330L | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV59492701; called by muse, mutect2, varscan2
- PTGES | c.244T>A p.F82I | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61393191; called by muse, mutect2
- PTPN23 | c.2768C>T p.T923I | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1389192363, COSV55545051; called by muse, mutect2, varscan2
- PTPRQ | c.1085A>T p.K362M (on ENST00000616559; = p.K320M on NM_001145026.2) | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV57041954; called by muse, mutect2, varscan2
- RXRA | c.1190A>G p.Y397C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs901061760, COSV62684376; called by muse, mutect2, varscan2
- SASH1 | c.814A>G p.R272G | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.395); catalogued as COSV66562124; called by mutect2, varscan2
- SMC4 | c.2161T>G p.L721V | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV61005384; called by muse, mutect2, varscan2
- SULT2B1 | c.299G>A p.R100Q (on ENST00000201586 / NM_177973.2; = p.R85Q on NM_004605.2) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs138292714; called by muse, mutect2, varscan2
- TM9SF2 | c.1538A>G p.E513G | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs773552636, COSV64506804; called by muse, mutect2, varscan2
- VPS13C | c.9193A>G p.T3065A (on ENST00000644861 / NM_020821.3; = p.T3022A on NM_017684.5) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51199465; called by muse, mutect2, varscan2
- ZNF607 | c.1984A>T p.I662L | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs371361210; called by muse, mutect2, varscan2
- AKNA | c.2231del p.L744Rfs*25 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- DCBLD2 | c.1577A>G p.D526G | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.989); called by muse, mutect2
- THSD1 | c.88_97del p.R30Afs*3 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- ZBTB10 | c.1492dup p.I498Nfs*16 | Frame Shift Ins (INS) | VAF 24/94 reads (26%) | called by mutect2, pindel, varscan2
- CLGN | c.1521A>G p.K507= | Silent (SNP) | VAF 12/242 reads (5%) | catalogued as COSV57774934; called by muse, mutect2
- DHX35 | c.537C>T p.H179= | Silent (SNP) | VAF 11/123 reads (9%) | catalogued as rs549854740, COSV52670600; called by muse, mutect2, varscan2
- DHX37 | c.1104G>C p.V368= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs1340857054, COSV58135088; called by muse, mutect2, varscan2
- DTHD1 | c.1191C>T p.N397= (on ENST00000456874; = p.N232= on NM_001136536.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/145 reads (25%) | catalogued as COSV62629257; called by muse, mutect2, varscan2
- EPB41L1 | c.114C>A p.G38= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV52438472; called by muse, mutect2, varscan2
- ITIH6 | c.1335C>T p.N445= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV54489708; called by muse, mutect2, varscan2
- MUC4 | c.5385C>A p.V1795= | Silent (SNP) | VAF 48/360 reads (13%) | catalogued as COSV62153065; called by muse, mutect2, varscan2
- SHOC1 | c.2985T>C p.D995= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV59502355; called by muse, mutect2, varscan2
- ZNF793 | c.681C>T p.H227= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as rs371897623; called by muse, mutect2, varscan2
- ZXDA | c.789C>T p.G263= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV62388082; called by muse, mutect2, varscan2
- AC107023.1 | n.25+5458T>A | Intron (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- CCDC150 | c.1866+750A>G | Intron (SNP) | VAF 12/144 reads (8%) | catalogued as rs767227654; called by muse, mutect2
- FUT9 | c.*924T>C | 3'UTR (SNP) | VAF 12/172 reads (7%) | catalogued as COSV100133132; called by muse, mutect2
- POM121C | chr7:75416072 G>A | 3'Flank (SNP) | VAF 25/77 reads (32%) | called by muse, mutect2, varscan2
